Somatic mutation profile of tumor specimen TCGA-21-1080-01A (aliquot TCGA-21-1080-01A-01W-0782-08) from TCGA case TCGA-21-1080, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.4 years (24,253 days).
Specimen TCGA-21-1080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23caea97-aa10-41ad-b68c-5d41c0c68333.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-21-1080-11A (Solid Tissue Normal), aliquot TCGA-21-1080-11A-01W-0782-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ab59083-3ba1-4fb1-8b45-50bbc8ebe5b5

The open-access MAF lists 1,128 somatic variants for this specimen: 861 protein-altering or splice-affecting, 239 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 639, Silent 239, Frame Shift Del 131, Nonsense Mutation 37, Frame Shift Ins 24, Splice Site 16, RNA 15, Intron 10, In Frame Del 8, Splice Region 5, 3'UTR 1, Translation Start Site 1.

Variants (750 of 1,128; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASR | c.108del p.L37Sfs*8 | Frame Shift Del (DEL) | VAF 81/308 reads (26%) | catalogued as rs886041823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CDKL5 | c.175C>T p.R59* | Nonsense Mutation (SNP) | VAF 32/44 reads (73%) | catalogued as rs62653623, CM063890, COSV66112951; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2728+2T>C p.X910_splice | Splice Site (SNP) | VAF 6/21 reads (29%) | catalogued as rs886038898, COSV100354990; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.3704del p.G1235Vfs*95 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1364500207, COSV99979040; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PARN | c.1257del p.F419Lfs*7 | Frame Shift Del (DEL) | VAF 58/157 reads (37%) | catalogued as rs942538351; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 29/54 reads (54%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PRKCI | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 25/103 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1388201066, COSV55517137, COSV55517929; called by muse, mutect2, varscan2
- TGFB2 | c.821dup p.N274Kfs*19 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | catalogued as rs863223796; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 25/43 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.2413G>A p.A805T | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV99933489; called by muse, mutect2, varscan2
- AASDH | c.1319del p.L440Wfs*43 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | catalogued as rs770970036; called by mutect2, varscan2
- ABCA1 | c.2869G>A p.A957T | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs755100870, COSV66063425; called by muse, mutect2, varscan2
- ABCA5 | c.4594A>G p.I1532V | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV101201133; called by muse, mutect2, varscan2
- ABCB10 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 53/172 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV100747942; called by muse, mutect2, varscan2
- AC020907.6 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 72/234 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.109); catalogued as rs758612609, COSV100032522; called by muse, mutect2, varscan2
- AC091959.1 | c.3073G>A p.A1025T | Missense Mutation (SNP) | VAF 113/360 reads (31%) | catalogued as rs977319468, COSV100047038, COSV100047220; called by muse, mutect2, varscan2
- ACACB | c.1942G>A p.V648I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376760625; called by muse, mutect2, varscan2
- ACSF2 | c.1797+2T>C p.X599_splice | Splice Site (SNP) | VAF 113/330 reads (34%) | catalogued as COSV99364253; called by muse, mutect2, varscan2
- ACSL6 | c.1730A>G p.Y577C (on ENST00000379240; = p.Y602C on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/160 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99733638; called by muse, mutect2, varscan2
- ACSM1 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 127/310 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as rs1429562270, COSV99532947; called by muse, mutect2, varscan2
- ACSM4 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.124); catalogued as COSV101257144; called by muse, mutect2, varscan2
- ADAM11 | c.1966G>A p.G656R | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1215505244, COSV52346188; called by muse, mutect2, varscan2
- ADAM22 | c.1685T>C p.V562A | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.125); catalogued as COSV99716814; called by muse, mutect2, varscan2
- ADAMTS20 | c.5026A>T p.K1676* | Nonsense Mutation (SNP) | VAF 11/167 reads (7%) | catalogued as COSV101239271; called by muse, mutect2
- ADAMTS6 | c.1892C>A p.P631H | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV66857158; called by muse, mutect2, varscan2
- ADGRB3 | c.512T>C p.L171S | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101000649; called by muse, mutect2, varscan2
- ADGRF5 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1216724132, COSV99345581; called by muse, mutect2, varscan2
- ADGRL1 | c.3830C>T p.A1277V (on ENST00000340736 / NM_001008701.3; = p.A1272V on NM_014921.5) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs775444088, COSV61565971; called by muse, varscan2
- ADGRV1 | c.16603A>C p.S5535R | Missense Mutation (SNP) | VAF 14/397 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV101315900; called by muse, mutect2
- AFAP1L1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs1413854340, COSV57044407, COSV57044996; called by muse, mutect2, varscan2
- AHNAK | c.6894del p.K2299Sfs*23 | Frame Shift Del (DEL) | VAF 142/366 reads (39%) | catalogued as COSV99947683; called by mutect2, pindel, varscan2
- AHNAK2 | c.1761A>G p.I587M | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as COSV100317442; called by muse, varscan2
- AIMP2 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.34); catalogued as rs756474990, COSV52241512; called by muse, mutect2, varscan2
- AK5 | c.1247C>T p.A416V (on ENST00000354567 / NM_174858.3; = p.A390V on NM_012093.4) | Missense Mutation (SNP) | VAF 87/310 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100642679; called by muse, mutect2, varscan2
- AK7 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs781727092, COSV50870814; called by muse, mutect2, varscan2
- AKAP3 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 74/177 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as COSV99962112; called by muse, varscan2
- AL121899.2 | c.537del p.G180Afs*13 | Frame Shift Del (DEL) | VAF 119/448 reads (27%) | catalogued as COSV101198511; called by mutect2, pindel, varscan2
- ALG13 | c.2535G>T p.M845I | Missense Mutation (SNP) | VAF 138/201 reads (69%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV99322173; called by muse, mutect2, varscan2
- ALS2CL | c.1363del p.Q455Sfs*83 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs765143111; called by mutect2, pindel, varscan2
- AMPH | c.1701G>T p.E567D | Missense Mutation (SNP) | VAF 69/123 reads (56%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100342007; called by muse, mutect2, varscan2
- ANGEL1 | c.1514G>A p.R505H | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.053); catalogued as rs775354721, COSV51873019; called by muse, mutect2, varscan2
- ANK3 | c.2063C>T p.A688V | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769188895, COSV55084703; called by muse, mutect2, varscan2
- ANKS1B | c.1560A>C p.K520N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.725); catalogued as COSV100245475; called by muse, mutect2, varscan2
- AOC1 | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV100710758; called by muse, mutect2, varscan2
- APBA1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 62/453 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.711); catalogued as rs777319156, COSV99596041; called by muse, mutect2, varscan2
- AQP7 | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs62542746; called by muse, mutect2, varscan2
- ARAP3 | c.3086G>A p.R1029H | Missense Mutation (SNP) | VAF 189/615 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs375379752; called by muse, mutect2, varscan2
- ARAP3 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 33/73 reads (45%) | catalogued as COSV99499692; called by muse, mutect2, varscan2
- ARHGAP26 | c.1160G>A p.S387N | Missense Mutation (SNP) | VAF 163/209 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs541692751, COSV99190924; called by muse, mutect2, varscan2
- ARHGAP36 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as COSV52266787, COSV99357664; called by muse, mutect2, varscan2
- ARHGEF10L | c.1393T>C p.F465L | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as COSV99392814; called by muse, mutect2, varscan2
- ARHGEF11 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 165/477 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as rs780733515, COSV100810081; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 70/184 reads (38%) | catalogued as rs749402223; called by mutect2, varscan2
- ARHGEF7 | c.1783C>T p.H595Y (on ENST00000375741 / NM_001113511.2; = p.H417Y on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/289 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV54543172, COSV99521504; called by muse, mutect2, varscan2
- ARPP21 | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 66/91 reads (73%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs775615764, COSV51794320, COSV99491995; called by muse, mutect2, varscan2
- ASB17 | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.398); catalogued as COSV99407929; called by muse, mutect2, varscan2
- ASH1L | c.4868G>A p.G1623D | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV100853407; called by muse, mutect2, varscan2
- ASTN1 | c.3797C>A p.A1266E | Missense Mutation (SNP) | VAF 112/306 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.018); catalogued as COSV100706651, COSV62494925; called by muse, mutect2, varscan2
- ASXL1 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299423705, COSV60107868, COSV60111358; called by muse, mutect2, varscan2
- ATAD3B | c.226A>T p.N76Y | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV100426447; called by muse, mutect2, varscan2
- ATG2B | c.3042G>T p.E1014D | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV100738003; called by muse, mutect2, varscan2
- ATPSCKMT | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 57/331 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs559270054, COSV54726807, COSV99725982; called by muse, mutect2, varscan2
- ATRNL1 | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100745378, COSV104421825; called by muse, mutect2, varscan2
- AXL | c.1517G>A p.R506H (on ENST00000301178 / NM_021913.5; = p.R497H on NM_001699.6) | Missense Mutation (SNP) | VAF 134/384 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1162584880, COSV56566309; called by muse, varscan2
- BAZ1A | c.2254G>T p.G752* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV100701146; called by muse, mutect2, varscan2
- BCAN | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as rs1257901341, COSV100228088; called by muse, mutect2, varscan2
- BIRC6 | c.12608C>A p.S4203Y | Missense Mutation (SNP) | VAF 178/482 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101428273; called by muse, mutect2, varscan2
- BPIFB4 | c.1264A>G p.M422V | Missense Mutation (SNP) | VAF 168/355 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100971517; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- BYSL | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.134); catalogued as rs1302608594; called by muse, mutect2
- C12orf66 | c.1093A>G p.I365V | Missense Mutation (SNP) | VAF 124/269 reads (46%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs1174546546, COSV100320729; called by muse, mutect2, varscan2
- C1QL2 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99733181; called by muse, mutect2, varscan2
- C1orf162 | c.401A>G p.H134R | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV100636211; called by muse, mutect2, varscan2
- C2CD3 | c.1429del p.I477* | Frame Shift Del (DEL) | VAF 76/207 reads (37%) | catalogued as rs1406007301, CD164515; called by mutect2, pindel, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs747591930; called by mutect2, varscan2
- C8orf34 | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs773229116, COSV100298161; called by muse, mutect2, varscan2
- CAB39L | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as COSV100759556; called by muse, mutect2, varscan2
- CACNA1B | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53124706, COSV53143006; called by muse, mutect2, varscan2
- CACNA1G | c.5188C>T p.R1730W | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773699484, COSV100661768; called by muse, varscan2
- CACNA1I | c.1963G>A p.V655I | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs543332325, COSV100360225; called by muse, mutect2, varscan2
- CACNG5 | c.509A>G p.Y170C | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.814); catalogued as COSV99400573; called by muse, mutect2, varscan2
- CADPS2 | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 92/230 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV57386159; called by muse, mutect2, varscan2
- CALB1 | c.508T>C p.L170= | Splice Region (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99618237; called by muse, mutect2
- CAPN2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 104/258 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1436682876, COSV99688873; called by muse, mutect2, varscan2
- CAPN5 | c.907C>T p.R303C (on ENST00000456580; = p.R263C on NM_004055.5) | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs373951153; called by muse, mutect2, varscan2
- CAPN7 | c.806A>G p.N269S | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as rs200044345, COSV99512762; called by muse, mutect2, varscan2
- CARMIL2 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.056); catalogued as rs1341756201, COSV100576066; called by muse, mutect2, varscan2
- CARMIL3 | c.854T>A p.I285N | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100549581; called by muse, mutect2, varscan2
- CASP8 | c.1286T>C p.L429P (on ENST00000432109 / NM_033355.3; = p.L446P on NM_001228.4) | Missense Mutation (SNP) | VAF 122/361 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51848774, COSV51859047; called by muse, mutect2, varscan2
- CASP8AP2 | c.2286C>G p.S762R | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV52750198, COSV99387045; called by muse, mutect2, varscan2
- CATSPER2 | c.791C>T p.S264L | Missense Mutation (SNP) | VAF 85/123 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as rs1047098503, COSV100390730, COSV58661532; called by muse, mutect2, varscan2
- CBLN2 | c.343A>T p.I115F | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99504372; called by muse, mutect2, varscan2
- CCDC136 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as rs372522612; called by muse, mutect2, varscan2
- CCDC157 | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147189543; called by muse, mutect2, varscan2
- CCDC38 | c.1686del p.F562Lfs*4 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | catalogued as rs769501825; called by mutect2, pindel
- CCDC40 | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV99481716; called by muse, mutect2, varscan2
- CCDC42 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs942378045, COSV53447943; called by muse, mutect2, varscan2
- CCDC8 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as rs759782532, COSV100282020; called by muse, mutect2, varscan2
- CCDC88C | c.3388G>A p.A1130T | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.094); catalogued as rs1064794398, COSV66238725, COSV66239297; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCS | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs367642079, COSV100039972; called by muse, mutect2, varscan2
- CD4 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 272/820 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs782481105, COSV99163764; called by muse, mutect2, varscan2
- CD70 | c.332C>T p.T111M | Missense Mutation (SNP) | VAF 69/176 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1378830614, COSV55565495; called by muse, mutect2, varscan2
- CD74 | c.308C>A p.P103H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99153735; called by muse, mutect2, varscan2
- CDC14B | c.820A>G p.T274A | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.289); catalogued as rs949080815, COSV99685665; called by muse, mutect2, varscan2
- CDC26 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 101/274 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs780745708, COSV65252945, COSV65252961; called by muse, mutect2, varscan2
- CDH18 | c.1915A>G p.S639G | Missense Mutation (SNP) | VAF 155/1353 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs764321747, COSV99934630; called by muse, mutect2, varscan2
- CDH23 | c.1474T>A p.F492I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.255); catalogued as COSV99820846; called by muse, mutect2, varscan2
- CDH24 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs189915240, COSV99399436; called by muse, mutect2, varscan2
- CDH26 | c.1579C>A p.L527M | Missense Mutation (SNP) | VAF 37/71 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs1302036224, COSV54857227, COSV99722379; called by muse, mutect2, varscan2
- CDH9 | c.273A>G p.I91M | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50306562; called by muse, mutect2, varscan2
- CDHR3 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100488332; called by muse, mutect2
- CDK18 | c.1262C>T p.A421V (on ENST00000506784 / NM_212503.3; = p.A391V on NM_002596.4) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as rs747475085, COSV63728515; called by muse, mutect2, varscan2
- CDK19 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100098493; called by muse, mutect2, varscan2
- CDK4 | c.179T>A p.L60Q | Missense Mutation (SNP) | VAF 68/196 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99225991; called by muse, mutect2, varscan2
- CENATAC | c.636G>T p.E212D | Missense Mutation (SNP) | VAF 72/245 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as COSV100548751; called by muse, mutect2, varscan2
- CEP128 | c.3196A>G p.T1066A | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99824625; called by muse, mutect2, varscan2
- CEP83 | c.533T>G p.I178R | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100352843; called by muse, mutect2, varscan2
- CFAP91 | c.256T>C p.Y86H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99847104; called by muse, mutect2, varscan2
- CFH | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs773509771, COSV62776437; called by muse, mutect2, varscan2
- CFHR4 | c.1411T>G p.F471V (on ENST00000367416 / NM_001201551.2; = p.F225V on NM_006684.5) | Missense Mutation (SNP) | VAF 95/215 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV99260360; called by muse, mutect2, varscan2
- CFP | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55950442; called by muse, mutect2, varscan2
- CFTR | c.4270T>C p.Y1424H | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99136018; called by muse, mutect2, varscan2
- CHAC1 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 77/128 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV101471072, COSV71436079; called by muse, mutect2, varscan2
- CHD8 | c.6500T>C p.V2167A (on ENST00000646647 / NM_001170629.2; = p.V1888A on NM_020920.4) | Missense Mutation (SNP) | VAF 116/336 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100765299; called by muse, mutect2, varscan2
- CHORDC1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100272027; called by muse, mutect2, varscan2
- CHRD | c.2332C>T p.R778W | Missense Mutation (SNP) | VAF 87/146 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs763421267, COSV52614554; called by muse, mutect2, varscan2
- CHRD | c.2456dup p.X819_splice | Splice Site (INS) | VAF 23/113 reads (20%) | catalogued as rs780409040; called by mutect2, varscan2
- CHST5 | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759449704, COSV60340736; called by muse, mutect2, varscan2
- CHST6 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM034087, COSV60001627; called by muse, mutect2, varscan2
- CIDEA | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100255074; called by muse, mutect2, varscan2
- CIITA | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1026200952, COSV100161884; called by muse, mutect2
- CIT | c.2093A>G p.E698G | Missense Mutation (SNP) | VAF 215/543 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV99949537; called by muse, varscan2
- CKAP4 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs767034363, COSV65172231; called by muse, mutect2, varscan2
- CLEC2D | c.56A>C p.N19T | Missense Mutation (SNP) | VAF 49/181 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV51996040; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 34/46 reads (74%) | catalogued as rs369752219; called by mutect2, varscan2
- CLTCL1 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.055); catalogued as rs782161735, COSV99595021; called by muse, mutect2, varscan2
- CNGA4 | c.1370A>G p.Y457C | Missense Mutation (SNP) | VAF 70/125 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101171800; called by muse, mutect2, varscan2
- CNGA4 | c.1655del p.G552Vfs*36 | Frame Shift Del (DEL) | VAF 24/50 reads (48%) | catalogued as COSV66006840; called by mutect2, pindel, varscan2
- CNOT1 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as rs768422744, COSV57766312; called by muse, mutect2, varscan2
- CNTLN | c.1341G>T p.Q447H | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV99264029; called by muse, mutect2, varscan2
- CNTNAP3 | c.1493G>T p.S498I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.038); catalogued as COSV52676071; called by muse, mutect2, varscan2
- CNTNAP5 | c.331A>T p.S111C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70502338; called by muse, mutect2, varscan2
- COG4 | c.1402C>T p.R468W | Missense Mutation (SNP) | VAF 70/225 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148569863; called by muse, mutect2, varscan2
- COL11A1 | c.179T>C p.F60S | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100616455; called by muse, mutect2, varscan2
- COL14A1 | c.1474A>G p.I492V | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV99919225; called by muse, mutect2, varscan2
- COL22A1 | c.4351T>A p.F1451I | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.159); catalogued as COSV100278370; called by muse, mutect2, varscan2
- COL4A2 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 32/199 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100847339; called by muse, varscan2
- COL4A2 | c.306G>T p.K102N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV100847340; called by muse, varscan2
- COL4A4 | c.4673C>T p.A1558V | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs760044982, COSV100306809; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A6 | c.4626del p.T1544Hfs*49 | Frame Shift Del (DEL) | VAF 16/92 reads (17%) | catalogued as rs746783819, COSV62016775; called by mutect2, varscan2
- COP1 | c.831+2T>C p.X277_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV100443258; called by muse, mutect2, varscan2
- CORIN | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1050473774, COSV56690539, COSV99903604; called by muse, mutect2, varscan2
- COX4I2 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs746465103, COSV101064224; called by muse, mutect2
- CPNE3 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs376221396; called by muse, mutect2, varscan2
- CPNE4 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV101456684; called by muse, mutect2, varscan2
- CPSF6 | c.1022C>T p.P341L | Missense Mutation (SNP) | VAF 70/214 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs775771978, COSV57015897; called by muse, mutect2, varscan2
- CREBBP | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs753319377, COSV99269965; called by muse, mutect2, varscan2
- CRYGC | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 128/357 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs559463428, COSV56409556; called by muse, mutect2, varscan2
- CSMD3 | c.6127G>C p.E2043Q (on ENST00000297405 / NM_001363185.1; = p.E1939Q on NM_052900.3) | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV99833767; called by muse, mutect2, varscan2
- CSMD3 | c.2942T>A p.I981K (on ENST00000297405 / NM_001363185.1; = p.I877K on NM_052900.3) | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99833769; called by muse, mutect2, varscan2
- CSRNP1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 108/183 reads (59%) | catalogued as rs1230198888, COSV99826862; called by muse, mutect2, varscan2
- CSTF2 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as COSV65895164; called by muse, mutect2, varscan2
- CTNNA3 | c.1801T>G p.L601V | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV101049092; called by muse, mutect2
- CTNND2 | c.1202G>A p.S401N | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV100476332; called by muse, mutect2, varscan2
- CUL4A | c.1934G>A p.G645E (on ENST00000375440 / NM_001008895.4; = p.G545E on NM_003589.3) | Missense Mutation (SNP) | VAF 55/128 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100417215; called by muse, mutect2, varscan2
- CUL9 | c.4262G>A p.R1421Q | Missense Mutation (SNP) | VAF 305/727 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs1299303442, COSV99335359; called by muse, mutect2, varscan2
- CUX1 | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV99471424; called by muse, mutect2, varscan2
- CYLD | c.913+1G>A p.X305_splice | Splice Site (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100282418; called by muse, mutect2, varscan2
- CYP2J2 | c.605A>T p.E202V | Missense Mutation (SNP) | VAF 156/361 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100968013; called by muse, mutect2, varscan2
- CYP2U1 | c.742T>A p.F248I | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100256703; called by muse, mutect2, varscan2
- DAAM1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100658383; called by muse, mutect2, varscan2
- DBR1 | c.1463A>T p.D488V | Missense Mutation (SNP) | VAF 144/873 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV99604482; called by muse, mutect2, varscan2
- DCAF17 | c.1231del p.S411Vfs*23 | Frame Shift Del (DEL) | VAF 36/88 reads (41%) | catalogued as rs755674655; called by mutect2, varscan2
- DCAF4L2 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as COSV100150877; called by muse, mutect2, varscan2
- DCAF4L2 | c.195T>A p.D65E | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as COSV100150878; called by muse, mutect2, varscan2
- DCBLD1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780427862, COSV51646948; called by muse, mutect2, varscan2
- DCP1A | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV99587752; called by muse, mutect2, varscan2
- DCX | c.1013C>A p.T338N (on ENST00000636035 / NM_001195553.2; = p.T333N on NM_000555.3) | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100576422; called by muse, mutect2, varscan2
- DDX18 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 153/466 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs371988552; called by muse, mutect2, varscan2
- DENND3 | c.3574G>A p.V1192I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99370918; called by muse, mutect2, varscan2
- DENND4B | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); catalogued as rs1004687936, COSV100339029; called by muse, mutect2
- DHCR24 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.35); catalogued as rs747327620, COSV64874488; called by muse, mutect2, varscan2
- DHRS13 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV60458819; called by muse, mutect2
- DHX36 | c.1606-2A>T p.X536_splice | Splice Site (SNP) | VAF 45/70 reads (64%) | catalogued as COSV100273579; called by muse, mutect2, varscan2
- DIRAS2 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.229); catalogued as COSV101005849; called by muse, mutect2, varscan2
- DLC1 | c.782C>A p.P261H | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs774528738, COSV99363024; called by muse, mutect2
- DNAH5 | c.877del p.R293Dfs*12 | Frame Shift Del (DEL) | VAF 137/807 reads (17%) | catalogued as COSV54201852; called by mutect2, pindel, varscan2
- DNAH7 | c.11455G>T p.D3819Y | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV100415125; called by muse, mutect2, varscan2
- DNAH7 | c.6166G>A p.A2056T | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100415128; called by muse, mutect2, varscan2
- DOP1A | c.2531A>G p.N844S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV99381836; called by muse, mutect2, varscan2
- DOP1A | c.5249A>G p.D1750G | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.265); catalogued as rs1026343264, COSV99381837; called by muse, mutect2, varscan2
- DPP4 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 156/473 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as COSV100858858; called by muse, mutect2, varscan2
- DPPA4 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs765508136, COSV100169419; called by muse, mutect2, varscan2
- DSCAML1 | c.2578G>A p.A860T (on ENST00000321322; = p.A800T on NM_020693.4) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.191); catalogued as COSV58381732; called by muse, mutect2, varscan2
- DUOX2 | c.3872G>T p.R1291M | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101199751; called by muse, mutect2
- DYNC1H1 | c.5728A>G p.T1910A | Missense Mutation (SNP) | VAF 42/74 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100794852; called by muse, mutect2, varscan2
- DYRK3 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 157/415 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.415); catalogued as rs781850677, COSV100895685; called by muse, mutect2, varscan2
- EBF3 | c.1250G>A p.R417H (on ENST00000355311 / NM_001375392.1; = p.R408H on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs149862226; called by muse, mutect2, varscan2
- ECPAS | c.5122C>T p.R1708C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs747464812, COSV99398236; called by muse, mutect2, varscan2
- EEFSEC | c.650C>T p.T217M | Missense Mutation (SNP) | VAF 92/463 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.39); catalogued as rs753789877, COSV54625055; called by muse, mutect2, varscan2
- EFNA4 | c.535del p.D179Tfs*15 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs754580525; called by pindel, varscan2
- EFR3A | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 135/495 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs371116230; called by muse, mutect2, varscan2
- EIF2AK4 | c.2609C>T p.A870V | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1217833277, COSV99774642; called by muse, mutect2
- ELAVL1 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 63/86 reads (73%) | SIFT tolerated (0.09); PolyPhen benign (0.418); catalogued as COSV100688096; called by muse, mutect2, varscan2
- ELMOD3 | c.363A>G p.K121= | Splice Region (SNP) | VAF 119/338 reads (35%) | catalogued as COSV100226260; called by muse, mutect2, varscan2
- EPG5 | c.4361G>A p.R1454H | Missense Mutation (SNP) | VAF 157/232 reads (68%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as rs766875773, COSV56348725; called by muse, mutect2, varscan2
- EPG5 | c.1610A>G p.E537G | Missense Mutation (SNP) | VAF 172/271 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99957207; called by muse, mutect2, varscan2
- ESPL1 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99229282; called by muse, mutect2, varscan2
- ETV5 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 118/434 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100112267; called by muse, mutect2, varscan2
- EVX2 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs778210096, COSV100420663; called by muse, varscan2
- EXOC3 | c.1611G>T p.E537D | Missense Mutation (SNP) | VAF 166/324 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV100155324; called by muse, mutect2, varscan2
- EXOC3 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.088); catalogued as COSV100155326; called by muse, mutect2
- FAM135B | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 101/363 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs757961854, COSV99423708; called by muse, mutect2, varscan2
- FAM81A | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99893174; called by muse, mutect2
- FAT4 | c.12431G>A p.R4144K | Missense Mutation (SNP) | VAF 96/147 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV58673092, COSV58707096; called by muse, mutect2, varscan2
- FBXO44 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.39); PolyPhen benign (0.243); catalogued as COSV99278878; called by muse, mutect2, varscan2
- FGD6 | c.1592G>C p.S531T | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.026); catalogued as rs866135561, COSV100676563; called by muse, mutect2, varscan2
- FGFR2 | c.1546G>A p.V516M | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100336179; called by muse, mutect2, varscan2
- FILIP1L | c.2920T>C p.S974P (on ENST00000354552 / NM_182909.3; = p.S734P on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/628 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100496816; called by muse, mutect2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 70/179 reads (39%) | catalogued as rs752076602; called by mutect2, varscan2
- FLG2 | c.3869A>G p.E1290G | Missense Mutation (SNP) | VAF 29/893 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101165847; called by muse, mutect2
- FLNC | c.4779T>A p.N1593K | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100368081; called by muse, mutect2
- FLRT2 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs769370773, COSV58138769; called by muse, mutect2, varscan2
- FMO5 | c.779del p.K260Rfs*2 | Frame Shift Del (DEL) | VAF 21/187 reads (11%) | catalogued as rs72549315; called by mutect2, pindel
- FNDC11 | c.212T>A p.L71Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100918793; called by muse, mutect2, varscan2
- FPR2 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 45/77 reads (58%) | catalogued as COSV100389279; called by muse, mutect2, varscan2
- FRY | c.3850C>A p.L1284I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100969242; called by muse, mutect2, varscan2
- FTSJ3 | c.2434C>T p.R812C | Missense Mutation (SNP) | VAF 30/708 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs771302233, COSV63791434; called by muse, mutect2
- FUT5 | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.779); catalogued as COSV99398739; called by muse, mutect2, varscan2
- GALNT10 | c.1073del p.G358Afs*82 | Frame Shift Del (DEL) | VAF 31/152 reads (20%) | catalogued as rs1320790513; called by mutect2, pindel, varscan2
- GALNT17 | c.880G>A p.G294R | Missense Mutation (SNP) | VAF 70/208 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61159704, COSV61160542, COSV61197845; called by muse, mutect2, varscan2
- GALNT3 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as rs368590625, COSV101204933; called by muse, mutect2, varscan2
- GBA2 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 133/304 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV100960204; called by muse, mutect2, varscan2
- GFOD2 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as rs771540117, COSV99263465; called by muse, mutect2
- GFPT2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs754688285, COSV99517622; called by muse, mutect2, varscan2
- GFRAL | c.630T>G p.C210W | Missense Mutation (SNP) | VAF 123/375 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100475124; called by muse, mutect2, varscan2
- GGT5 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.36); catalogued as COSV54068952, COSV99571530; called by muse, mutect2, varscan2
- GIGYF2 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV65247111; called by muse, mutect2, varscan2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs750227570; called by mutect2, varscan2
- GJD2 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 51/84 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as COSV99290728; called by muse, mutect2, varscan2
- GLUD2 | c.448A>T p.I150F | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV100046806; called by muse, mutect2, varscan2
- GNAL | c.323A>G p.N108S (on ENST00000269162 / NM_001142339.3; = p.N185S on NM_182978.4) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV99303486; called by muse, mutect2, varscan2
- GNG11 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV50350388; called by muse, mutect2, varscan2
- GOLGA1 | c.1530G>T p.K510N | Missense Mutation (SNP) | VAF 286/871 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100764447; called by muse, mutect2, varscan2
- GOLGB1 | c.2461G>C p.D821H | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV100510822; called by muse, mutect2, varscan2
- GPAM | c.32T>C p.I11T | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated, low confidence (0.42); PolyPhen probably damaging (0.966); catalogued as rs201270796, COSV100788206; called by muse, mutect2, varscan2
- GPATCH1 | c.2165A>T p.E722V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.238); catalogued as COSV99404008; called by muse, mutect2, varscan2
- GPATCH8 | c.2848A>G p.T950A | Missense Mutation (SNP) | VAF 65/170 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100132643; called by muse, mutect2, varscan2
- GPR146 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.212); catalogued as COSV99866360; called by muse, varscan2
- GPR149 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV101078425; called by muse, varscan2
- GPR173 | c.424G>C p.A142P | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100212193, COSV100212248, COSV100212429; called by muse, mutect2, varscan2
- GPR20 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1301244197, COSV100897314; called by muse, mutect2, varscan2
- GRHL1 | c.668A>G p.E223G | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV100257798; called by muse, mutect2, varscan2
- GRIN2A | c.2696G>A p.R899Q | Missense Mutation (SNP) | VAF 168/246 reads (68%) | SIFT tolerated (0.4); PolyPhen benign (0.269); catalogued as rs759145938, COSV58055440; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRK1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.925); catalogued as rs200986774; called by muse, mutect2, varscan2
- GSPT2 | c.1503A>C p.E501D | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as rs1471802343, COSV100468147; called by muse, mutect2, varscan2
- GTPBP1 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99323175; called by muse, mutect2, varscan2
- GUCA1C | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99659682; called by muse, mutect2, varscan2
- GUCY1A2 | c.2122C>G p.P708A | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.039); catalogued as COSV56494585, COSV99974601; called by muse, mutect2, varscan2
- GUCY2F | c.1701+2T>G p.X567_splice | Splice Site (SNP) | VAF 154/181 reads (85%) | catalogued as COSV99484952; called by muse, mutect2, varscan2
- H4C6 | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as rs866041115, COSV100897489; called by muse, mutect2, varscan2
- HAUS6 | c.482A>G p.D161G | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100787215; called by muse, mutect2, varscan2
- HCFC1 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100128973, COSV60077670; called by muse, mutect2, varscan2
- HDAC8 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.377); catalogued as COSV101003297; called by muse, mutect2
- HDLBP | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 121/404 reads (30%) | catalogued as rs1559497188, COSV100190555; called by muse, mutect2, varscan2
- HEPH | c.1233T>A p.S411R (on ENST00000343002; = p.S144R on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100294813; called by muse, mutect2, varscan2
- HERC2 | c.10712C>T p.A3571V | Missense Mutation (SNP) | VAF 65/188 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.048); catalogued as rs151205330; called by muse, mutect2, varscan2
- HESX1 | c.133T>G p.W45G | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99907725; called by muse, mutect2, varscan2
- HGD | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV99380930; called by muse, mutect2, varscan2
- HIVEP1 | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 45/137 reads (33%) | catalogued as COSV101045123; called by muse, mutect2, varscan2
- HK2 | c.966del p.K323Sfs*34 | Frame Shift Del (DEL) | VAF 98/435 reads (23%) | catalogued as rs1558801241; called by mutect2, varscan2
- HLTF | c.869G>A p.G290E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768864078, COSV100026846, COSV100026962; called by muse, mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs761272507; called by mutect2, varscan2
- HNF1B | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 82/256 reads (32%) | catalogued as CM153591; called by muse, varscan2
- HNF4A | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.081); catalogued as rs1222461881, COSV100291365; called by muse, mutect2, varscan2
- HSP90B1 | c.1056_1058del p.E352del | In Frame Del (DEL) | VAF 16/77 reads (21%) | catalogued as rs1454903094; called by pindel, varscan2
- HSPA2 | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV99904932; called by muse, mutect2, varscan2
- HTR1E | c.41T>A p.I14K | Missense Mutation (SNP) | VAF 85/211 reads (40%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV100541094; called by muse, mutect2, varscan2
- HUWE1 | c.4948C>T p.R1650* | Nonsense Mutation (SNP) | VAF 17/340 reads (5%) | catalogued as COSV99472220; called by muse, mutect2
- IGF2BP2 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.305); catalogued as rs751050074, COSV100649115; called by muse, mutect2, varscan2
- IGHV3-7 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 60/846 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs536437057; called by muse, mutect2
- IGSF10 | c.5173G>A p.A1725T | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779602494, COSV56789051; called by muse, mutect2, varscan2
- IKBKB | c.83A>T p.N28I | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV100645695; called by muse, mutect2, varscan2
- IKZF4 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777888384, COSV100009099; called by muse, varscan2
- IL11RA | c.1169G>A p.W390* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99426478; called by muse, mutect2, varscan2
- IL12RB1 | c.754G>T p.G252W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100443001; called by muse, mutect2, varscan2
- INPPL1 | c.2918C>T p.A973V | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs753171921, COSV53358010; called by mutect2, varscan2
- INSL6 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as rs994783034, COSV101068476; called by muse, mutect2, varscan2
- IQCJ | c.350C>A p.P117H | Missense Mutation (SNP) | VAF 151/487 reads (31%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as COSV101188424; called by muse, mutect2, varscan2
- IQGAP2 | c.4297G>T p.A1433S | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.038); catalogued as COSV99167233; called by muse, mutect2, varscan2
- ISX | c.33G>T p.R11S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as COSV58087853; called by muse, mutect2, varscan2
- ITFG2 | c.634T>C p.C212R | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1288505412, COSV99958151; called by muse, mutect2, varscan2
- ITGB3 | c.995T>C p.L332S | Missense Mutation (SNP) | VAF 152/375 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101457598; called by muse, mutect2, varscan2
- JMY | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 106/174 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs1278817116, COSV101268013; called by muse, mutect2, varscan2
- KALRN | c.5654A>C p.N1885T (on ENST00000360013 / NM_001024660.4; = p.N188T on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99361999; called by muse, mutect2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 12/18 reads (67%) | catalogued as rs1206265094; called by mutect2, varscan2
- KBTBD3 | c.1807A>G p.R603G | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV101595688; called by muse, mutect2, varscan2
- KCNH6 | c.2765C>T p.A922V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as rs373179436; called by muse, mutect2, varscan2
- KCNJ14 | c.281_283del p.S94del | In Frame Del (DEL) | VAF 15/23 reads (65%) | catalogued as rs774240298; called by mutect2, pindel, varscan2
- KCNK9 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs768019389, COSV57282856, COSV57290433; called by muse, mutect2, varscan2
- KCNN4 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 127/431 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202202107, COSV99487051; called by muse, mutect2, varscan2
- KCTD15 | c.337G>A p.V113I | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs199530630; called by muse, mutect2, varscan2
- KCTD9 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55339890; called by muse, mutect2, varscan2
- KDM1A | c.1771C>T p.R591* | Nonsense Mutation (SNP) | VAF 37/91 reads (41%) | catalogued as COSV63088329; called by muse, mutect2, varscan2
- KDM6A | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 28/36 reads (78%) | catalogued as COSV65041233, COSV65048505; called by muse, mutect2, varscan2
- KHDC4 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100850800; called by muse, mutect2, varscan2
- KHDRBS2 | c.545A>T p.E182V | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.093); catalogued as COSV99833517; called by muse, mutect2, varscan2
- KIAA0100 | c.5963G>A p.R1988H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1173569754, COSV99972076; called by muse, mutect2, varscan2
- KIAA1109 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs375276784; called by muse, mutect2, varscan2
- KIAA1109 | c.3305A>G p.H1102R | Missense Mutation (SNP) | VAF 106/156 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs773900426, COSV99163248; called by muse, mutect2, varscan2
- KIAA1217 | c.4835G>A p.G1612D | Missense Mutation (SNP) | VAF 9/237 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440753145, COSV56823694; called by muse, mutect2
- KIAA1755 | c.2060T>G p.V687G | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99641990; called by muse, mutect2, varscan2
- KIF27 | c.2417A>C p.K806T | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99926964; called by muse, varscan2
- KIF3A | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 37/248 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV101109331, COSV66416309; called by muse, mutect2, varscan2
- KLHL20 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV52942459; called by muse, mutect2, varscan2
- KLHL24 | c.1754A>G p.H585R | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99664917; called by muse, mutect2, varscan2
- KLHL6 | c.1642C>G p.R548G | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV100384615; called by muse, mutect2, varscan2
- KLHL6 | c.30G>T p.W10C | Missense Mutation (SNP) | VAF 65/409 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV100384618; called by muse, mutect2, varscan2
- KMT2C | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as rs1273259441, COSV100071641; called by muse, mutect2, varscan2
- KMT2D | c.4394C>G p.P1465R | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56478566, COSV99981465; called by muse, mutect2, varscan2
- KNG1 | c.614A>T p.N205I | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768936464, COSV53977756, COSV99405532; called by muse, mutect2, varscan2
- KPNA5 | c.776T>C p.V259A | Missense Mutation (SNP) | VAF 16/275 reads (6%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.558); catalogued as COSV100706221; called by muse, mutect2
- KY | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 182/712 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.694); catalogued as rs185575980; called by muse, mutect2, varscan2
- L3MBTL4 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs986386240, COSV99528885; called by muse, mutect2, varscan2
- LATS1 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1045863115, COSV99485953; called by muse, mutect2
- LCT | c.3245G>T p.G1082V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as COSV51551021, COSV99929442; called by muse, mutect2, varscan2
- LCT | c.2771C>T p.A924V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs867449499, COSV99929445; called by muse, mutect2, varscan2
- LLGL1 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.13); catalogued as COSV100375352; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 36/59 reads (61%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LNPEP | c.434del p.N145Tfs*6 | Frame Shift Del (DEL) | VAF 80/134 reads (60%) | catalogued as rs748712732; called by mutect2, varscan2
- LOXL4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.538); catalogued as rs142324231, COSV53259560; called by muse, mutect2
- LPCAT1 | c.1420G>A p.A474T | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs767227485, COSV99359003; called by muse, mutect2, varscan2
- LRCH4 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1318708986, COSV59642745; called by muse, mutect2, varscan2
- LRP1 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54510175; called by muse, mutect2
- LRP1 | c.13300C>G p.L4434V | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54509929; called by muse, mutect2, varscan2
- LRP2 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 76/277 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV99788358; called by muse, mutect2, varscan2
- LRP3 | c.1684A>G p.I562V | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV99472247; called by muse, mutect2, varscan2
- LRP5 | c.4108T>C p.C1370R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1317111394, COSV99591948; called by muse, mutect2, varscan2
- LRRC41 | c.1779G>T p.E593D | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV100586326; called by muse, mutect2, varscan2
- LRRC6 | c.146T>C p.L49P | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99137984; called by muse, mutect2, varscan2
- LRRIQ4 | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 49/273 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as rs745609351, COSV100540243; called by muse, mutect2, varscan2
- LRRN4 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1303514639, COSV101125449; called by muse, mutect2, varscan2
- LRRTM4 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297551; called by muse, mutect2, varscan2
- LSR | c.383A>G p.Y128C | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100670458; called by muse, mutect2, varscan2
- LYN | c.818C>A p.A273D | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101319601; called by muse, mutect2, varscan2
- LYPD2 | c.4C>T p.R2W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs766328861, COSV63650015; called by muse, mutect2, varscan2
- LYRM9 | c.35G>T p.R12M | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100991838; called by muse, mutect2, varscan2
- MACC1 | c.2189T>C p.V730A | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV100255789; called by muse, mutect2, varscan2
- MAN2B2 | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs1012918606, COSV99577401; called by muse, mutect2, varscan2
- MAP7D3 | c.2383A>G p.T795A | Missense Mutation (SNP) | VAF 16/273 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1289783890, COSV60170162; called by muse, mutect2
- MAPK15 | c.1203C>A p.H401Q | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.09); catalogued as COSV100567873; called by muse, mutect2
- MARCHF6 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 64/304 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as rs757462388, COSV56889297; called by muse, varscan2
- MARS1 | c.2264T>C p.M755T | Missense Mutation (SNP) | VAF 146/306 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs745605073, COSV100007345; called by muse, mutect2, varscan2
- MASP1 | c.1465G>C p.A489P | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100536535, COSV100537229; called by muse, mutect2, varscan2
- MAST2 | c.1589G>T p.R530L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs756217180, COSV100788086; called by muse, mutect2, varscan2
- MAST4 | c.5255C>T p.A1752V (on ENST00000403625 / NM_001164664.2; = p.A1563V on NM_015183.3) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.127); catalogued as rs1370142279, COSV99844124; called by muse, mutect2, varscan2
- MAVS | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780062135, COSV100816306; called by muse, mutect2
- MC1R | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.871); catalogued as rs1484000912, COSV59624541; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCC | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 51/78 reads (65%) | SIFT tolerated (0.49); PolyPhen benign (0.037); catalogued as COSV56728628; called by muse, mutect2, varscan2
- MCHR2 | c.831G>T p.M277I | Missense Mutation (SNP) | VAF 102/221 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99911991; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCHR2 | c.185C>A p.S62Y | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as COSV99911992, COSV99912440; called by muse, mutect2, varscan2
- MCM10 | c.2392G>A p.V798I (on ENST00000484800 / NM_182751.3; = p.V797I on NM_018518.5) | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as rs374760775, COSV101097971; called by muse, mutect2, varscan2
- MECOM | c.425A>G p.D142G (on ENST00000468789 / NM_001105078.4; = p.D330G on NM_004991.4) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99244673; called by muse, mutect2, varscan2
- MED13L | c.3665C>A p.P1222H | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99928779; called by muse, mutect2, varscan2
- MED23 | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 16/101 reads (16%) | catalogued as COSV100644986; called by muse, mutect2, varscan2
- MEI1 | c.2039G>A p.R680H | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1448940976, COSV100299937; called by muse, mutect2, varscan2
- MFGE8 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 265/432 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs368495899; called by muse, mutect2, varscan2
- MGARP | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV101299202, COSV101299210; called by muse, mutect2, varscan2
- MLH1 | c.755C>G p.S252* | Nonsense Mutation (SNP) | VAF 13/23 reads (57%) | catalogued as CM158550, CM941060, COSV51613882, COSV99212440; called by muse, mutect2, varscan2
- MME | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs772484156, COSV100852386; called by muse, mutect2, varscan2
- MMP24 | c.1483C>T p.R495W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as rs746247860, COSV55768875; called by mutect2, varscan2
- MMS19 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs567643385, COSV100512854; called by muse, mutect2, varscan2
- MRPL47 | c.256A>G p.T86A | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs1335981344, COSV99372554; called by muse, mutect2, varscan2
- MSH4 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV99591561; called by muse, mutect2, varscan2
- MSS51 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 97/231 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs773556183, COSV100200249, COSV55019555; called by muse, mutect2, varscan2
- MTHFR | c.1645A>T p.T549S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV100453617; called by muse, varscan2
- MTMR6 | c.1739A>G p.D580G | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as rs1191590525, COSV101110775; called by muse, mutect2, varscan2
- MUC16 | c.41143A>C p.S13715R | Missense Mutation (SNP) | VAF 32/425 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.92); catalogued as COSV101109886; called by muse, mutect2
- MUC16 | c.11666T>C p.V3889A | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as COSV101199874; called by muse, mutect2, varscan2
- MVB12B | c.316C>G p.H106D | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV100752819, COSV63261791; called by muse, mutect2, varscan2
- MYBL2 | c.1721T>C p.L574P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV99406310; called by muse, mutect2, varscan2
- MYH15 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV99843214; called by muse, mutect2, varscan2
- MYO1D | c.1759G>A p.V587I | Missense Mutation (SNP) | VAF 47/158 reads (30%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.591); catalogued as rs143604215; called by muse, mutect2, varscan2
- MYO5C | c.609C>T p.A203= | Splice Region (SNP) | VAF 14/30 reads (47%) | catalogued as rs768341396, COSV55907445; called by muse, mutect2, varscan2
- MYO7A | c.5002T>C p.Y1668H | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101289127; called by muse, mutect2, varscan2
- MYOM2 | c.3940C>T p.R1314C | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142380219; called by muse, mutect2, varscan2
- N4BP3 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1411925905, COSV51063190; called by muse, mutect2, varscan2
- NALCN | c.2768A>G p.Y923C | Missense Mutation (SNP) | VAF 111/135 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778344856, COSV99215047; called by muse, mutect2, varscan2
- NALCN | c.2349A>T p.E783D | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); catalogued as COSV99215052; called by muse, mutect2, varscan2
- NARS2 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs754348995, COSV99807190; called by muse, mutect2, varscan2
- NAV1 | c.1858A>G p.M620V | Missense Mutation (SNP) | VAF 144/397 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs766385399, COSV99818792; called by muse, mutect2, varscan2
- NAV3 | c.6569G>A p.R2190K (on ENST00000397909 / NM_001024383.2; = p.R2168K on NM_014903.6) | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99890679; called by muse, mutect2, varscan2
- NBEA | c.4383C>A p.N1461K | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100080008; called by muse, mutect2, varscan2
- NCAPD3 | c.4218G>T p.E1406D | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV101592167; called by muse, mutect2, varscan2
- NCOA2 | c.2335A>G p.T779A | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV101475962; called by muse, mutect2, varscan2
- NDST2 | c.2526+1G>T p.X842_splice | Splice Site (SNP) | VAF 43/73 reads (59%) | catalogued as rs554839383, COSV100013963; called by muse, mutect2, varscan2
- NEB | c.13426C>T p.R4476C | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs765644258, COSV51469361; called by muse, mutect2, varscan2
- NEB | c.9055G>A p.A3019T | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs753256008, COSV50814349; called by muse, mutect2, varscan2
- NECAP2 | c.575del p.P192Qfs*8 | Frame Shift Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs57163901; called by mutect2, pindel, varscan2
- NECTIN1 | c.827del p.P276Qfs*10 | Frame Shift Del (DEL) | VAF 27/116 reads (23%) | catalogued as rs1565387426, COSV99872379; called by mutect2, pindel, varscan2
- NEDD9 | c.758C>A p.P253Q | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.322); catalogued as rs200144366, COSV101060836; called by muse, mutect2, varscan2
- NEIL1 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as rs1262433075, COSV99145405; called by muse, mutect2, varscan2
- NF1 | c.7717G>T p.A2573S (on ENST00000358273 / NM_001042492.3; = p.A2552S on NM_000267.3) | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as COSV100646997; called by muse, mutect2, varscan2
- NFX1 | c.2456A>G p.D819G | Missense Mutation (SNP) | VAF 66/460 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as rs755131177, COSV100582113; called by muse, mutect2, varscan2
- NLGN1 | c.1307T>A p.I436N | Missense Mutation (SNP) | VAF 80/285 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100849329; called by muse, mutect2, varscan2
- NLK | c.1114G>A p.A372T | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs911610122, COSV100817301; called by muse, mutect2, varscan2
- NLRC4 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs374259187; called by muse, mutect2
- NLRC5 | c.3330G>T p.R1110S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.084); catalogued as COSV52659880, COSV99347243; called by muse, mutect2, varscan2
- NME9 | c.397G>T p.A133S (on ENST00000333911 / NM_001349024.2; = p.A72S on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.057); catalogued as COSV100444745; called by muse, mutect2, varscan2
- NPHP1 | c.501A>T p.Q167H | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100338050; called by muse, mutect2, varscan2
- NRN1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 101/294 reads (34%) | catalogued as COSV99784155; called by muse, mutect2, varscan2
- NT5C1A | c.968C>A p.P323Q | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99348425; called by muse, mutect2, varscan2
- NTM | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 169/413 reads (41%) | catalogued as COSV100868384; called by muse, mutect2, varscan2
- NTN4 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 210/517 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs769530917, COSV100643767; called by muse, mutect2, varscan2
- NUF2 | c.358T>G p.F120V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.864); catalogued as COSV54842216; called by muse, varscan2
- NUMA1 | c.3051G>T p.Q1017H | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV100706130; called by muse, mutect2, varscan2
- NUP188 | c.3071C>T p.P1024L | Missense Mutation (SNP) | VAF 103/238 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101001206; called by muse, mutect2, varscan2
- NUP205 | c.4423G>T p.A1475S | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as rs566540964, COSV99606971; called by muse, mutect2, varscan2
- NUP205 | c.5137C>T p.R1713C | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763400589; called by muse, mutect2
- NXPE4 | c.887G>A p.C296Y (on ENST00000375478 / NM_001077639.2; = p.C12Y on NM_017678.3) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100970434; called by muse, mutect2, varscan2
- NXPH2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55641949, COSV55642800; called by muse, mutect2, varscan2
- NYAP2 | c.1951A>G p.N651D | Missense Mutation (SNP) | VAF 678/1888 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.034); catalogued as COSV99796561; called by muse, varscan2
- OAS2 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT tolerated (0.88); PolyPhen benign (0.04); catalogued as COSV60803051; called by muse, mutect2
- ODF2L | c.1367G>A p.G456D (on ENST00000317336; = p.G427D on NM_020729.3) | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99644149; called by muse, mutect2, varscan2
- OR10G4 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 116/345 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100304824; called by muse, mutect2, varscan2
- OR10G7 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 165/535 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs747708955, COSV100389919; called by muse, mutect2, varscan2
- OR1J1 | c.674T>A p.I225N | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV99403146; called by muse, mutect2, varscan2
- OR2T6 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs371476686, COSV63215950; called by muse, mutect2, varscan2
- OR4C15 | c.71T>A p.I24K | Missense Mutation (SNP) | VAF 96/347 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100115650; called by muse, mutect2, varscan2
- OR4D11 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 171/812 reads (21%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.515); catalogued as COSV100506546; called by muse, mutect2, varscan2
- OR4K2 | c.844C>A p.L282M | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV100064472, COSV53851037; called by muse, mutect2, varscan2
- OR51B6 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV100971267; called by muse, mutect2, varscan2
- OR52A1 | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 52/79 reads (66%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100200481, COSV61092361; called by muse, mutect2, varscan2
- OR52J3 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984868; called by muse, mutect2
- OR52K2 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 575/861 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100355722; called by muse, mutect2, varscan2
- OR5D14 | c.511T>C p.S171P | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.433); catalogued as COSV100162362; called by muse, mutect2
- OR5L1 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100450049; called by muse, mutect2
- OR5L2 | c.673A>G p.I225V | Missense Mutation (SNP) | VAF 173/338 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.162); catalogued as COSV101004310; called by muse, mutect2, varscan2
- OR5M11 | c.689C>A p.A230E | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV101602039; called by muse, mutect2, varscan2
- OR6C6 | c.337C>A p.L113M | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100626463, COSV64456066; called by muse, mutect2, varscan2
- OR6K2 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 108/228 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs532035184, COSV62743770; called by muse, mutect2, varscan2
- OR6K6 | c.182T>C p.L61P (on ENST00000368144; = p.L37P on NM_001005184.1) | Missense Mutation (SNP) | VAF 141/375 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); catalogued as rs1558026140, COSV100933740; called by muse, mutect2, varscan2
- OR6T1 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 70/220 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.038); catalogued as COSV58309984; called by muse, mutect2, varscan2
- OR8D4 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.088); catalogued as COSV100361813; called by muse, mutect2
- OR8H1 | c.806G>T p.R269M | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV100477082; called by muse, mutect2, varscan2
- OR8J3 | c.212T>A p.L71H | Missense Mutation (SNP) | VAF 79/209 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100040826; called by muse, mutect2, varscan2
- OSGEP | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777404578, COSV99247989; called by muse, varscan2
- OSGEP | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99247993; called by muse, varscan2
- OSGEPL1 | c.813A>G p.E271= | Splice Region (SNP) | VAF 5/16 reads (31%) | catalogued as COSV99918379; called by muse, mutect2, varscan2
- OSMR | c.246+2T>C p.X82_splice | Splice Site (SNP) | VAF 22/63 reads (35%) | catalogued as COSV99953125; called by muse, mutect2, varscan2
- OSR2 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99882570; called by muse, mutect2
- OTUD5 | c.1558C>T p.R520W | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as COSV99331945; called by muse, mutect2, varscan2
- OXCT1 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 116/793 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as COSV99542110; called by muse, mutect2, varscan2
- PAPPA2 | c.4343G>C p.C1448S | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62791209; called by muse, mutect2, varscan2
- PARP11 | c.550A>G p.K184E | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV99959010; called by muse, mutect2, varscan2
- PAX8 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs368109291; called by muse, mutect2, varscan2
- PBRM1 | c.773del p.N258Mfs*25 | Frame Shift Del (DEL) | VAF 41/78 reads (53%) | catalogued as COSV56262297; called by mutect2, pindel, varscan2
- PC | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100852217; called by muse, mutect2, varscan2
- PCDH10 | c.2650G>T p.E884* | Nonsense Mutation (SNP) | VAF 19/29 reads (66%) | catalogued as COSV99993511; called by muse, mutect2, varscan2
- PCDH11Y | c.3833G>A p.G1278D | Missense Mutation (SNP) | VAF 1242/1378 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV99291436; called by muse, mutect2, varscan2
- PCDH7 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1298790860; called by muse, varscan2
- PCDH8 | c.2936A>G p.H979R | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100131618; called by muse, mutect2, varscan2
- PCDHA13 | c.245G>A p.G82D | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99166242; called by muse, mutect2
- PCDHA8 | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 173/238 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as COSV65336618; called by muse, mutect2, varscan2
- PCDHA9 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.777); catalogued as COSV100969368; called by muse, mutect2, varscan2
- PCDHAC1 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.604); catalogued as COSV53848317; called by muse, mutect2, varscan2
- PCDHB15 | c.832T>A p.S278T | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.05); catalogued as COSV99178913; called by muse, mutect2, varscan2
- PCDHGA1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.477); catalogued as COSV65296356; called by muse, mutect2, varscan2
- PCDHGC5 | c.2293C>T p.R765W | Missense Mutation (SNP) | VAF 78/103 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV99338383; called by muse, mutect2, varscan2
- PCLO | c.9933G>C p.K3311N | Missense Mutation (SNP) | VAF 144/292 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1430283344, COSV100432316; called by muse, mutect2, varscan2
- PCLO | c.4343A>G p.D1448G | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV100432322; called by muse, mutect2, varscan2
- PCLO | c.2519G>A p.S840N | Missense Mutation (SNP) | VAF 88/299 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs867009906, COSV100432328; called by muse, mutect2, varscan2
- PCNT | c.3311A>C p.Q1104P | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100855466; called by muse, mutect2, varscan2
- PCSK5 | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1280710018, COSV100950012; called by muse, mutect2, varscan2
- PDE3A | c.1238G>T p.S413I | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.067); catalogued as COSV100762093; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 14/19 reads (74%) | catalogued as rs747131399; called by mutect2, varscan2
- PER2 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); catalogued as rs774249054, COSV54526377; called by muse, mutect2, varscan2
- PFN4 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 156/423 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.545); catalogued as rs780066510, COSV57531841; called by muse, mutect2, varscan2
- PGR | c.2104G>T p.G702* | Nonsense Mutation (SNP) | VAF 226/613 reads (37%) | catalogued as COSV54795898, COSV54810645; called by muse, mutect2, varscan2
- PHF19 | c.115A>T p.K39* | Nonsense Mutation (SNP) | VAF 83/175 reads (47%) | catalogued as COSV100384317; called by muse, mutect2, varscan2
- PHF20L1 | c.2629G>A p.A877T | Missense Mutation (SNP) | VAF 68/245 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758054864, COSV99621230; called by muse, mutect2, varscan2
- PHTF2 | c.1709del p.L570Cfs*4 (on ENST00000248550 / NM_001366089.1; = p.L532Cfs*4 on NM_020432.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | catalogued as rs775426168; called by mutect2, varscan2
- PIAS1 | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51032835; called by muse, mutect2, varscan2
- PICALM | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs1172716942, COSV100707853; called by muse, mutect2, varscan2
- PIK3R4 | c.1633C>A p.L545I | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as COSV100768391; called by muse, varscan2
- PKD1L1 | c.6806del p.G2269Afs*6 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as COSV99221378; called by pindel, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | catalogued as rs745860467; called by mutect2, varscan2
- PLCB1 | c.767C>A p.P256H | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV100570907; called by muse, mutect2, varscan2
- PLEC | c.9251C>T p.T3084M (on ENST00000322810 / NM_201380.4; = p.T2974M on NM_000445.5) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs782130064, COSV100513890; called by muse, mutect2
- PLEKHG1 | c.2699T>G p.L900R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as COSV100651614; called by muse, mutect2, varscan2
- PLEKHG3 | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775460208, COSV99906584; called by muse, varscan2
- PLEKHG3 | c.1645A>G p.I549V (on ENST00000394691; = p.I605V on NM_001308147.2) | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99906586; called by muse, mutect2, varscan2
- PLIN3 | c.806T>G p.L269R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99701552; called by muse, mutect2, varscan2
- PLXNA1 | c.4429A>G p.I1477V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.895); catalogued as COSV99303005; called by muse, mutect2, varscan2
- PLXNA4 | c.2080C>T p.R694* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as rs997228646, COSV100324178; called by muse, mutect2, varscan2
- PODN | c.820A>G p.S274G (on ENST00000395871; = p.S226G on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.111); catalogued as COSV100439539; called by muse, mutect2, varscan2
- POLE2 | c.859T>C p.F287L | Missense Mutation (SNP) | VAF 113/379 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV99364762; called by muse, mutect2, varscan2
- POLR2K | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as COSV100777489; called by muse, mutect2, varscan2
- POMC | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53035024; called by muse, mutect2, varscan2
- POMT1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/95 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1488276082, COSV100260986; called by muse, mutect2, varscan2
- POSTN | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs750422217, COSV65712849; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1292G>A p.C431Y | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as COSV99461255; called by muse, mutect2, varscan2
- PPFIA1 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs749928660, COSV99557402; called by muse, mutect2, varscan2
- PPIG | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as rs1558904194, COSV53643187; called by muse, mutect2
- PPP2R5D | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 111/256 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.221); catalogued as COSV57841664; called by muse, mutect2, varscan2
- PPP2R5D | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 91/260 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs1176068332, COSV99776535; called by muse, mutect2, varscan2
- PRAMEF8 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as rs1407476713; called by muse, mutect2, varscan2
- PRDM2 | c.2299G>A p.G767R | Missense Mutation (SNP) | VAF 106/197 reads (54%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as rs200363632, COSV52444132; called by muse, mutect2, varscan2
- PRDM9 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 195/656 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV99690414; called by muse, varscan2
- PRELID1 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100293580; called by muse, mutect2, varscan2
- PROX1 | c.1715C>T p.S572L | Missense Mutation (SNP) | VAF 103/245 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV54775784; called by muse, mutect2, varscan2
- PRPS1L1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 194/294 reads (66%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs770382539, COSV72649976; called by muse, mutect2, varscan2
- PSD | c.750del p.S251Afs*43 | Frame Shift Del (DEL) | VAF 4/9 reads (44%) | catalogued as rs761494960; called by mutect2, varscan2
- PSG8 | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 112/509 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100126173; called by muse, mutect2, varscan2
- PTPN3 | c.2146G>A p.A716T | Missense Mutation (SNP) | VAF 96/269 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs763936455, COSV52705938; called by muse, mutect2, varscan2
- PTPN3 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355713; called by muse, mutect2, varscan2
- PTPRN2 | c.2381G>A p.S794N | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.047); catalogued as COSV101234379; called by muse, mutect2, varscan2
- PTPRU | c.2998C>T p.R1000W | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1040440432, COSV100112358; called by muse, mutect2, varscan2
- PYDC1 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs377601641; called by muse, mutect2, varscan2
- RAB11FIP4 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100365422; called by muse, mutect2, varscan2
- RAB5A | c.217A>G p.I73V | Missense Mutation (SNP) | VAF 77/107 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99810954; called by muse, mutect2, varscan2
- RABL6 | c.640A>G p.M214V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs763926444, COSV100273306; called by muse, mutect2, varscan2
- RAD1 | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100337573; called by muse, mutect2, varscan2
- RALGDS | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100924433; called by muse, mutect2, varscan2
- RAP1GAP | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 113/190 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs376034636; called by muse, mutect2, varscan2
- RBBP6 | c.2527A>G p.K843E | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as COSV100154586; called by muse, mutect2, varscan2
- RBM18 | c.304C>T p.R102* | Nonsense Mutation (SNP) | VAF 74/262 reads (28%) | catalogued as rs749662781, COSV69874138; called by muse, mutect2, varscan2
- RBM42 | c.1109A>G p.D370G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99387002; called by muse, mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as rs749563266; called by mutect2, varscan2
- RC3H2 | c.2720C>T p.A907V | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV61801430; called by muse, mutect2, varscan2
- RCE1 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs560263038, COSV58994087; called by muse, mutect2, varscan2
- RFTN1 | c.1648A>G p.I550V | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); catalogued as COSV100489261; called by muse, mutect2, varscan2
- RFX6 | c.2327G>T p.S776I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as COSV60589924; called by muse, mutect2, varscan2
- RFX7 | c.2323A>G p.N775D (on ENST00000559447 / NM_001368074.1; = p.N872D on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100428751; called by muse, mutect2, varscan2
- RHEB | c.200A>T p.Y67F | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.048); catalogued as COSV100062102; called by muse, mutect2
- RINT1 | c.1603C>T p.R535* | Nonsense Mutation (SNP) | VAF 107/323 reads (33%) | catalogued as rs764298491, COSV99994381; called by muse, mutect2, varscan2
- RIOX1 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 78/283 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100408021; called by muse, mutect2, varscan2
- RIOX2 | c.1313T>G p.V438G (on ENST00000333396 / NM_001042533.2; = p.V437G on NM_032778.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99476971; called by muse, mutect2, varscan2
- RND3 | c.570del p.H191Tfs*8 | Frame Shift Del (DEL) | VAF 47/168 reads (28%) | catalogued as COSV55723383; called by mutect2, pindel, varscan2
- RNF149 | c.981G>T p.Q327H | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV99766566; called by muse, mutect2, varscan2
- RNF31 | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99396044; called by muse, mutect2, varscan2
- RNLS | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV100076507; called by muse, mutect2, varscan2
- RO60 | c.788T>A p.L263* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV100814376; called by muse, mutect2, varscan2
- RORC | c.156+2T>C p.X52_splice | Splice Site (SNP) | VAF 8/164 reads (5%) | catalogued as COSV100561938; called by muse, mutect2
- RP1 | c.4420C>A p.H1474N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99607417; called by muse, mutect2, varscan2
- RPL19 | c.467+1G>A p.X156_splice | Splice Site (SNP) | VAF 13/37 reads (35%) | catalogued as COSV99841454; called by muse, mutect2, varscan2
- RSPH6A | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs777585850, COSV99679771; called by muse, mutect2, varscan2
- RTTN | c.3572A>G p.Q1191R | Missense Mutation (SNP) | VAF 91/133 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.295); catalogued as COSV99732286; called by muse, mutect2, varscan2
- RUFY2 | c.697C>G p.Q233E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as COSV100700113; called by muse, mutect2, varscan2
- RUSC2 | c.4309C>T p.Q1437* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as rs1199886841, COSV100770707, COSV63428701; called by muse, mutect2, varscan2
- RYK | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV99938418; called by muse, mutect2, varscan2
- RYR1 | c.12571C>T p.R4191C | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62107633; called by muse, mutect2, varscan2
- RYR2 | c.13417C>A p.P4473T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs571824543, COSV100770027; called by muse, mutect2, varscan2
- SALL1 | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV99173791; called by muse, mutect2, varscan2
- SALL1 | c.1954G>A p.A652T | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs776664263, COSV51761952; called by muse, mutect2, varscan2
- SAMD3 | c.554A>T p.Y185F | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV100148240; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 63/230 reads (27%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SCAMP1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs762983897, COSV100210458; called by muse, mutect2, varscan2
- SCAMP2 | c.223dup p.Q75Pfs*134 | Frame Shift Ins (INS) | VAF 9/36 reads (25%) | catalogued as rs1304394803; called by mutect2, pindel, varscan2
- SCFD1 | c.1826A>G p.D609G | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.715); catalogued as COSV100356368; called by muse, varscan2
- SCLY | c.695G>T p.G232V (on ENST00000651534; = p.G224V on NM_016510.7) | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV99615682; called by muse, mutect2, varscan2
- SCN2A | c.971-2A>C p.X324_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV99331589; called by muse, mutect2, varscan2
- SCN4A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 120/301 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV71126633; called by muse, mutect2, varscan2
- SDK2 | c.6308C>T p.T2103M | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as rs202216577; called by muse, mutect2, varscan2
- SEC23B | c.1864C>A p.Q622K | Missense Mutation (SNP) | VAF 59/222 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV52719245, COSV99357678; called by muse, mutect2, varscan2
- SEC24B | c.2536G>A p.D846N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99493439; called by muse, mutect2, varscan2
- SEC31A | c.3181C>A p.Q1061K (on ENST00000355196 / NM_001318120.1; = p.Q1022K on NM_016211.4) | Missense Mutation (SNP) | VAF 118/199 reads (59%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.831); catalogued as COSV100021858; called by muse, mutect2, varscan2
- SEMA4F | c.192T>A p.N64K | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as COSV100336005; called by muse, mutect2
- SEMA4G | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs139918504; called by muse, mutect2, varscan2
- SEMA5A | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66793768; called by muse, varscan2
- SEMG1 | c.1373A>C p.N458T | Missense Mutation (SNP) | VAF 160/379 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.024); catalogued as COSV99725245; called by muse, varscan2
- SERPINA11 | c.1017A>C p.E339D | Missense Mutation (SNP) | VAF 196/440 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV100594035, COSV100594197; called by muse, mutect2, varscan2
- SERPINI1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.917); catalogued as rs781486255, COSV55508060, COSV99855064; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINI1 | c.872A>G p.Y291C | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV99855065; called by muse, mutect2, varscan2
- SERTAD1 | c.190C>A p.L64M | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100781688; called by muse, varscan2
- SESTD1 | c.1443-1G>T p.X481_splice | Splice Site (SNP) | VAF 103/298 reads (35%) | catalogued as COSV100090487; called by muse, mutect2, varscan2
- SETD2 | c.5935C>G p.P1979A | Missense Mutation (SNP) | VAF 71/110 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100338958, COSV57437473; called by muse, mutect2, varscan2
- SFSWAP | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as COSV99906076; called by muse, mutect2, varscan2
- SH2D5 | c.610G>A p.E204K (on ENST00000444387 / NM_001103161.2; = p.E120K on NM_001103160.2) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.41); PolyPhen benign (0.423); catalogued as COSV100903838; called by muse, varscan2
- SI | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs544498038, COSV100015475; called by muse, mutect2, varscan2
- SIGLEC1 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs771244528, COSV52458581; called by muse, mutect2, varscan2
- SIPA1L1 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 88/239 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62168879; called by muse, varscan2
- SIPA1L3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs148442622; called by muse, mutect2, varscan2
- SIX1 | c.66G>T p.Q22H | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV55959597, COSV99903339; called by muse, mutect2, varscan2
- SLC12A4 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100311747; called by muse, mutect2, varscan2
- SLC17A1 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.107); catalogued as rs929731540, COSV99765753; called by muse, mutect2, varscan2
- SLC25A12 | c.1564_1566del p.L522del | In Frame Del (DEL) | VAF 38/122 reads (31%) | catalogued as rs1293764094; called by pindel, varscan2
- SLC25A13 | c.30G>C p.K10N | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV99673598; called by muse, mutect2, varscan2
- SLC26A4 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM030963, COSV99072589, COSV99706929; called by muse, mutect2, varscan2
- SLC29A3 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV64385871; called by muse, mutect2, varscan2
- SLC29A3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs142991278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC5A6 | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs142184276; called by muse, mutect2, varscan2
- SLC6A11 | c.1625_1627del p.N542del | In Frame Del (DEL) | VAF 104/180 reads (58%) | catalogued as rs1420781036; called by pindel, varscan2
- SLC6A4 | c.1631T>C p.I544T | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99911362; called by muse, mutect2, varscan2
- SLC8A3 | c.1957G>A p.A653T (on ENST00000381269 / NM_183002.3; = p.A651T on NM_033262.4) | Missense Mutation (SNP) | VAF 64/210 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV53689916, COSV99385501; called by muse, mutect2, varscan2
- SLC9A8 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1162576578, COSV64287165; called by muse, mutect2, varscan2
- SLCO5A1 | c.777T>A p.N259K | Missense Mutation (SNP) | VAF 307/374 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99479977; called by muse, mutect2, varscan2
- SLFN5 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs763472910, COSV55481879; called by muse, mutect2, varscan2
- SMARCA5 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.8); PolyPhen benign (0.029); catalogued as COSV99303810; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as rs760667210; called by mutect2, varscan2
- SMPD2 | c.70A>T p.K24* | Nonsense Mutation (SNP) | VAF 10/22 reads (45%) | catalogued as COSV99237967; called by muse, mutect2, varscan2
- SMPD2 | c.71A>T p.K24M | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99237968; called by muse, mutect2, varscan2
- SMYD1 | c.1146G>T p.M382I | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV101352440; called by muse, mutect2, varscan2
- SNX19 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as rs576402537, COSV56289310; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 49/89 reads (55%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SOX7 | c.739G>A p.A247T | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1417374815, COSV100449069; called by muse, mutect2, varscan2
- SP100 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 142/496 reads (29%) | catalogued as COSV50975872; called by muse, mutect2, varscan2
- SP6 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100647020; called by muse, mutect2, varscan2
- SPACA3 | c.436A>G p.N146D | Missense Mutation (SNP) | VAF 166/434 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.165); catalogued as COSV99284176; called by muse, mutect2, varscan2
- SPEG | c.8905C>A p.L2969M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.832); catalogued as COSV100405823, COSV56680805; called by muse, mutect2, varscan2
- SPEN | c.3788G>T p.S1263I | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV101005219; called by muse, mutect2, varscan2
- SPG7 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV99244899; called by muse, mutect2, varscan2
- SPINT1 | c.1384+1G>T p.X462_splice (on ENST00000344051 / NM_181642.3; = p.X446_splice on NM_003710.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 47/70 reads (67%) | catalogued as COSV100689054; called by muse, mutect2, varscan2
- SPRED2 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749197715, COSV100710076; called by muse, mutect2
- SSTR1 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as COSV99942881; called by muse, mutect2, varscan2
- ST20 | c.88A>T p.M30L | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV51914305; called by muse, mutect2, varscan2
- ST7 | c.954G>A p.M318I (on ENST00000265437 / NM_021908.3; = p.M295I on NM_018412.4) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as rs1414140811, COSV99621873; called by muse, mutect2, varscan2
- STAG3 | c.616C>A p.L206I | Missense Mutation (SNP) | VAF 135/346 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV100425900; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 58/122 reads (48%) | catalogued as rs752994755; called by mutect2, varscan2
- STAT1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 236/643 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV63116964; called by muse, mutect2, varscan2
- STAT5A | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.419); catalogued as COSV100604593; called by muse, mutect2, varscan2
- STC1 | c.430G>A p.A144T | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV99282493; called by muse, mutect2, varscan2
- STOML3 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1198988261, COSV65510816; called by muse, mutect2
- STRAP | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV99214773; called by muse, mutect2, varscan2
- STXBP5L | c.3241G>T p.G1081C | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874016; called by muse, mutect2, varscan2
- SUGT1 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100139485; called by muse, mutect2, varscan2
- SUPT6H | c.2023G>T p.G675* | Nonsense Mutation (SNP) | VAF 31/157 reads (20%) | catalogued as COSV100112391; called by muse, mutect2, varscan2
- SVEP1 | c.7568C>A p.S2523Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.543); catalogued as COSV52838003, COSV99928976; called by muse, mutect2, varscan2
- SYCP3 | c.643del p.I215Lfs*2 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs761136347, CD035010; called by mutect2, varscan2
- SYDE1 | c.427dup p.Q143Pfs*250 | Frame Shift Ins (INS) | VAF 14/45 reads (31%) | catalogued as rs1195849144; called by mutect2, pindel, varscan2
- SYMPK | c.2502G>T p.M834I | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.027); catalogued as COSV99841716; called by muse, mutect2, varscan2
- SYNDIG1 | c.310del p.D104Tfs*38 | Frame Shift Del (DEL) | VAF 20/134 reads (15%) | catalogued as COSV100965383; called by mutect2, pindel, varscan2
- SYNE1 | c.16804dup p.M5602Nfs*13 (on ENST00000367255 / NM_182961.4; = p.M5531Nfs*13 on NM_033071.3) | Frame Shift Ins (INS) | VAF 20/73 reads (27%) | catalogued as rs1368275632; called by mutect2, pindel, varscan2
- TAF15 | c.1249G>A p.G417S (on ENST00000605844 / NM_139215.3; = p.G414S on NM_003487.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs554593706; called by muse, mutect2
- TAFA5 | c.122C>A p.A41D (on ENST00000402357 / NM_001082967.3; = p.A34D on NM_015381.7) | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.852); catalogued as COSV100385566, COSV100385982; called by muse, mutect2, varscan2
- TAGAP | c.2131C>T p.R711* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as COSV57851534; called by muse, mutect2, varscan2
- TAGAP | c.1996C>T p.R666* | Nonsense Mutation (SNP) | VAF 33/151 reads (22%) | catalogued as rs769810341, COSV57851540; called by muse, mutect2, varscan2
- TARS1 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs200221822; called by muse, mutect2, varscan2
- TAX1BP1 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV99604446; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 21/68 reads (31%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D25 | c.1792C>T p.P598S | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV100952146; called by muse, mutect2, varscan2
- TBC1D5 | c.1322A>T p.N441I | Missense Mutation (SNP) | VAF 100/137 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as COSV99510441; called by muse, mutect2, varscan2
- TBCE | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100783054; called by muse, mutect2, varscan2
- TBL3 | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776297421, COSV60343625; called by muse, varscan2
- TBR1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV101271466; called by muse, mutect2
- TCTE3 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs149245139; called by muse, mutect2, varscan2
- TDRD6 | c.4082C>T p.A1361V | Missense Mutation (SNP) | VAF 154/607 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100287566, COSV100287912; called by muse, mutect2, varscan2
- TECTA | c.4366G>A p.V1456M | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99879045; called by muse, mutect2, varscan2
- TET1 | c.5338C>T p.R1780* | Nonsense Mutation (SNP) | VAF 105/242 reads (43%) | catalogued as COSV65383466; called by muse, mutect2, varscan2
- TF | c.720C>G p.D240E | Missense Mutation (SNP) | VAF 69/294 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as COSV53924833; called by muse, mutect2, varscan2
- TGM6 | c.1799A>T p.K600M | Missense Mutation (SNP) | VAF 40/224 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99171779; called by muse, mutect2, varscan2
- THBS3 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs528865017, COSV57426338; called by muse, mutect2, varscan2
- THSD7A | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1156455476, COSV101448510, COSV101448919, COSV70265909; called by muse, mutect2, varscan2
- TIE1 | c.2048T>C p.V683A | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as COSV100992073; called by muse, mutect2, varscan2
- TLDC2 | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371243226; called by muse, mutect2, varscan2
- TLN2 | c.6251C>T p.A2084V | Missense Mutation (SNP) | VAF 94/175 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1410456933, COSV100168968; called by muse, mutect2, varscan2
- TMBIM4 | c.520del p.Y174Ifs*4 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs754390908; called by mutect2, varscan2
- TMEM100 | c.296del p.L99Yfs*2 | Frame Shift Del (DEL) | VAF 74/187 reads (40%) | catalogued as rs894486999; called by mutect2, varscan2
- TMEM244 | c.370T>A p.S124T | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100933566; called by muse, varscan2
- TMEM26 | c.442C>A p.L148I | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV53263141; called by muse, mutect2, varscan2
- TMEM45A | c.375A>T p.L125F | Missense Mutation (SNP) | VAF 189/718 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as rs544008446, COSV100058373; called by muse, mutect2, varscan2
- TMTC1 | c.2264G>A p.R755H (on ENST00000539277 / NM_001193451.2; = p.R647H on NM_175861.3) | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746225876, COSV55488017; called by muse, mutect2, varscan2
- TNFAIP8L1 | c.10T>G p.F4V | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100542397; called by muse, mutect2, varscan2
- TNFRSF11B | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 206/766 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV99816630; called by muse, mutect2, varscan2
- TNXB | c.10409del p.G3470Afs*51 (on ENST00000647633; = p.G3223Afs*51 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs773500008; called by mutect2, pindel, varscan2
- TOGARAM1 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as rs774550576, COSV61889049; called by muse, mutect2, varscan2
- TPD52L3 | c.418C>T p.P140S | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100095998; called by muse, mutect2
- TPH2 | c.418A>G p.N140D | Missense Mutation (SNP) | VAF 182/504 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100422072; called by muse, mutect2, varscan2
- TRAPPC5 | c.482C>T p.T161M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58040023; called by muse, mutect2, varscan2
- TRIM55 | c.82A>C p.I28L | Missense Mutation (SNP) | VAF 143/279 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99396777; called by muse, mutect2, varscan2
- TRIM59 | c.604del p.S202Vfs*3 | Frame Shift Del (DEL) | VAF 29/57 reads (51%) | catalogued as rs763112993; called by mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | catalogued as rs752676391; called by mutect2, varscan2
- TRMT5 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 74/138 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV99712107; called by muse, mutect2, varscan2
- TRPM3 | c.4088A>G p.E1363G (on ENST00000357533 / NM_001366142.2; = p.E1218G on NM_020952.6) | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100677279; called by muse, mutect2, varscan2
- TRPV4 | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 92/116 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs879254304, COSV99924673; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSPOAP1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143930252; called by muse, mutect2, varscan2
- TTC38 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV66844301, COSV66845451; called by muse, mutect2, varscan2
- TTN | c.86605C>T p.Q28869* (on ENST00000591111; = p.Q21445* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 29/47 reads (62%) | catalogued as COSV100598327; called by muse, mutect2, varscan2
- TTN | c.7619G>A p.R2540H (on ENST00000591111; = p.R2494H on NM_003319.4) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | PolyPhen benign (0); catalogued as rs397517725, COSV60264227, COSV99045902; ClinVar: uncertain significance / benign / likely benign; called by muse, mutect2, varscan2
- TUBA3C | c.1204C>T p.R402W | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as rs397839867, COSV68029415; called by muse, mutect2
- TUBB6 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99301870; called by muse, varscan2
- TUBGCP4 | c.1546C>T p.R516C (on ENST00000260383 / NM_001286414.3; = p.R515C on NM_014444.5) | Missense Mutation (SNP) | VAF 146/210 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as rs776182570, COSV99539062; called by muse, mutect2, varscan2
- TXLNB | c.1493C>T p.T498I | Missense Mutation (SNP) | VAF 89/185 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV100624940; called by muse, mutect2, varscan2
- UBR4 | c.5722C>T p.R1908C | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64389545; called by muse, mutect2
- UGCG | c.748T>C p.F250L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.014); catalogued as COSV100958950; called by muse, mutect2, varscan2
- UGP2 | c.1071+2T>C p.X357_splice | Splice Site (SNP) | VAF 15/71 reads (21%) | catalogued as COSV100451602; called by muse, mutect2, varscan2
- UNC13A | c.4295C>A p.A1432E | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99408253; called by muse, mutect2, varscan2
- UNC13B | c.3569C>T p.A1190V | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as rs1220495451, COSV101036642; called by muse, mutect2, varscan2
- UNC79 | c.4607C>T p.A1536V (on ENST00000393151 / NM_001346218.2; = p.A1359V on NM_020818.5) | Missense Mutation (SNP) | VAF 71/275 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); catalogued as rs771051532, COSV99827734; called by muse, mutect2, varscan2
- UROC1 | c.450G>T p.E150D | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.107); catalogued as COSV99331417; called by muse, mutect2, varscan2
- USF3 | c.439del p.I147Lfs*22 | Frame Shift Del (DEL) | VAF 50/194 reads (26%) | catalogued as rs747493460; called by mutect2, varscan2
- USH2A | c.1340A>G p.Y447C | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1553250638, CM149192, COSV100234342; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- USP17L2 | c.1453T>A p.S485T | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.25); catalogued as COSV100414596; called by muse, mutect2, varscan2
- USP20 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 151/283 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1306239981, COSV100204304; called by muse, mutect2, varscan2
- USP33 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 82/184 reads (45%) | catalogued as COSV100657105; called by muse, mutect2, varscan2
- USP36 | c.2417del p.Q806Rfs*91 | Frame Shift Del (DEL) | VAF 22/42 reads (52%) | catalogued as COSV61751095, COSV61753835; called by mutect2, varscan2
- USP40 | c.3292A>T p.T1098S | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.27); PolyPhen benign (0.222); catalogued as COSV99296396; called by muse, mutect2, varscan2
- USP45 | c.2374_2377del p.L792Rfs*25 | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | catalogued as rs756461122; called by pindel, varscan2
- UTP14C | c.39C>G p.S13R | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV101584289; called by muse, mutect2, varscan2
- UTP20 | c.3842A>G p.Y1281C | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); catalogued as COSV99881590; called by muse, mutect2
- VAV3 | c.697T>C p.S233P | Missense Mutation (SNP) | VAF 60/222 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.427); catalogued as COSV100579722; called by muse, mutect2, varscan2
- VEPH1 | c.848T>A p.F283Y | Missense Mutation (SNP) | VAF 181/728 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0.176); catalogued as COSV100747547; called by muse, mutect2, varscan2
- WDFY3 | c.6796G>A p.A2266T | Missense Mutation (SNP) | VAF 32/43 reads (74%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV99883479; called by muse, mutect2, varscan2
- WDR26 | c.1223C>T p.A408V (on ENST00000414423 / NM_001379403.1; = p.A308V on NM_025160.7) | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs879188103; called by muse, mutect2, varscan2
- WDR49 | c.1355A>G p.Y452C (on ENST00000308378 / NM_001366158.1; = p.Y793C on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV100392704; called by muse, mutect2, varscan2
- WNT7B | c.875G>A p.R292H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100254952; called by muse, mutect2, varscan2
- WWOX | c.864G>A p.W288* | Nonsense Mutation (SNP) | VAF 9/124 reads (7%) | catalogued as COSV101283028; called by muse, mutect2
- WWP1 | c.616T>C p.Y206H | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs189923427, COSV55361612, COSV99616369; called by muse, mutect2, varscan2
- XIRP2 | c.9128C>T p.P3043L (on ENST00000628543; = p.P3218L on NM_152381.6) | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99742688; called by muse, mutect2, varscan2
- XYLB | c.1405G>C p.A469P | Missense Mutation (SNP) | VAF 81/135 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52916498, COSV99264184; called by muse, mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- YEATS2 | c.3824G>A p.R1275H | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs777644621, COSV100527779; called by muse, mutect2, varscan2
- YIPF1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 103/325 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs141644838; called by muse, mutect2, varscan2
- YLPM1 | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99459602; called by muse, mutect2, varscan2
- ZBTB14 | c.362A>G p.D121G | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV100813456; called by muse, mutect2, varscan2
- ZBTB16 | c.69G>T p.K23N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.491); catalogued as COSV100251455; called by muse, mutect2, varscan2
- ZBTB24 | c.293A>T p.Y98F | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.285); catalogued as COSV100018442; called by muse, mutect2, varscan2
- ZCCHC17 | c.501G>T p.E167D | Missense Mutation (SNP) | VAF 103/246 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100703988; called by muse, mutect2, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFP69 | c.1067T>A p.V356E | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.287); catalogued as COSV101018219; called by muse, mutect2, varscan2
- ZFR | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 82/360 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54051436; called by muse, varscan2
- ZFY | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs754040681, COSV99324213; called by muse, mutect2, varscan2
- ZIC3 | c.1220T>C p.M407T | Missense Mutation (SNP) | VAF 68/90 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99798908; called by muse, mutect2, varscan2
- ZKSCAN7 | c.861T>A p.F287L | Missense Mutation (SNP) | VAF 154/193 reads (80%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99837610; called by muse, mutect2, varscan2
- ZNF142 | c.1231C>A p.L411M (on ENST00000411696 / NM_001379660.1; = p.L211M on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.239); catalogued as COSV101376938; called by muse, mutect2, varscan2
- ZNF229 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 44/623 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV99350390; called by muse, mutect2
- ZNF287 | c.492G>T p.L164F | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV101209377; called by muse, mutect2, varscan2
- ZNF311 | c.1718A>G p.H573R | Missense Mutation (SNP) | VAF 27/332 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453759609, COSV101014133; called by muse, mutect2
- ZNF311 | c.1266G>T p.R422S | Missense Mutation (SNP) | VAF 76/198 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as rs979851329, COSV101014134; called by muse, mutect2, varscan2
- ZNF318 | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 58/196 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs146670568; called by muse, mutect2, varscan2
- ZNF329 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.989); catalogued as COSV100798735; called by muse, mutect2, varscan2
- ZNF333 | c.1517A>G p.Y506C | Missense Mutation (SNP) | VAF 291/619 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV99469128; called by muse, mutect2, varscan2
- ZNF34 | c.875G>A p.C292Y | Missense Mutation (SNP) | VAF 77/210 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs750815056, COSV100603286; called by muse, mutect2, varscan2
- ZNF35 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.088); catalogued as COSV99940038; called by muse, mutect2, varscan2
- ZNF420 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100421344; called by muse, mutect2, varscan2
- ZNF45 | c.1322A>G p.E441G | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1354225488, COSV54192413, COSV54192754; called by muse, mutect2
- ZNF484 | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.46); PolyPhen benign (0.113); catalogued as COSV100214552, COSV100214648; called by muse, mutect2, varscan2
- ZNF500 | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99556311; called by muse, mutect2, varscan2
- ZNF500 | c.1115A>T p.Q372L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV99556312; called by muse, mutect2, varscan2
- ZNF574 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 256/1248 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs771441304, COSV99726108; called by muse, varscan2
- ZNF587 | c.581A>G p.K194R | Missense Mutation (SNP) | VAF 204/344 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100299445; called by muse, mutect2, varscan2
- ZNF676 | c.1336A>C p.I446L (on ENST00000650058; = p.I414L on NM_001001411.3) | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV101236198; called by muse, mutect2, varscan2
- ZNF697 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.913); catalogued as COSV101360153; called by muse, mutect2, varscan2
- ZNF700 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as rs1273705190, COSV99039050; called by muse, varscan2
- ZNF800 | c.1322del p.K441Rfs*61 | Frame Shift Del (DEL) | VAF 28/71 reads (39%) | catalogued as rs1346638445; called by mutect2, pindel, varscan2
- ZNF831 | c.814G>T p.A272S | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.044); catalogued as COSV100926014, COSV64038265; called by muse, mutect2, varscan2
- ZNF862 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1329262526, COSV56224774; called by muse, mutect2, varscan2
- ZSWIM5 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 143/372 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs1041772782, COSV62734011; called by muse, varscan2
378 further variants in this file (111 protein-altering or splice-affecting, 239 silent, 28 other) are not listed here.
